Somatic mutation profile of tumor specimen TCGA-GC-A6I3-01A (aliquot TCGA-GC-A6I3-01A-11D-A31L-08) from TCGA case TCGA-GC-A6I3, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 90 years or older (exact value withheld by GDC).
Specimen TCGA-GC-A6I3-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3b1dd6d8-c4e6-44ef-92c9-13a4ca70e7ff.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-GC-A6I3-10A (Blood Derived Normal), aliquot TCGA-GC-A6I3-10A-01D-A31J-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5ca43972-df03-484f-b171-fba1568ad282

The open-access MAF lists 246 somatic variants for this specimen: 175 protein-altering or splice-affecting, 64 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 154, Silent 64, Nonsense Mutation 13, Splice Region 4, RNA 3, Intron 3, In Frame Del 2, Splice Site 2, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1634A>C p.E545A | Missense Mutation (SNP) | VAF 8/36 reads (22%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.932); catalogued as rs121913274, CM130273, COSV55873209, COSV55873220, COSV55892885; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.473G>A p.R158H | Missense Mutation (SNP) | VAF 22/82 reads (27%) | hotspot (GDC flag); SIFT tolerated (0.1); PolyPhen possibly damaging (0.45); catalogued as rs587782144, CM102353, CM165595, CM994513, COSV52676395, COSV52678258, COSV52680378, COSV53545833; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCC8 | c.2407G>A p.E803K | Missense Mutation (SNP) | VAF 42/116 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.043); catalogued as rs369426518, COSV56849082; called by muse, mutect2, varscan2
- ACOX2 | c.385C>A p.L129M | Missense Mutation (SNP) | VAF 18/119 reads (15%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.459); catalogued as COSV57148513; called by muse, mutect2, varscan2
- ACY3 | c.126G>C p.Q42H | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.02); catalogued as COSV99662925; called by muse, mutect2
- ADAM29 | c.479C>T p.S160L | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV63662611; called by muse, mutect2, varscan2
- ADAMTS5 | c.1951G>A p.E651K | Missense Mutation (SNP) | VAF 9/97 reads (9%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.985); catalogued as COSV53178028; called by muse, mutect2
- ADGRL2 | c.3226C>T p.Q1076* (on ENST00000370717 / NM_001366005.1; = p.Q1063* on NM_012302.4) | Nonsense Mutation (SNP) | VAF 8/82 reads (10%) | catalogued as COSV54684132; called by muse, mutect2
- ADGRL4 | c.967G>A p.D323N | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT tolerated (0.53); PolyPhen benign (0.009); catalogued as COSV66061072, COSV66066339; called by muse, mutect2, varscan2
- ADRM1 | c.725C>A p.P242Q | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.689); catalogued as COSV53357940, COSV99437947; called by muse, mutect2, varscan2
- AGGF1 | c.715A>G p.I239V | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.743); catalogued as COSV57228572; called by muse, mutect2, varscan2
- AK6 | c.123G>A p.E41= | Splice Region (SNP) | VAF 14/57 reads (25%) | catalogued as COSV66458641; called by muse, mutect2, varscan2
- ALAS2 | c.148C>G p.Q50E | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT tolerated (0.56); PolyPhen benign (0.021); catalogued as COSV58189642; called by muse, mutect2, varscan2
- ALG6 | c.1036A>G p.K346E | Missense Mutation (SNP) | VAF 11/116 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV54764542; called by muse, mutect2
- ALK | c.4219G>A p.E1407K | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV66564650; called by muse, mutect2, varscan2
- AMER1 | c.1141G>A p.E381K | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); catalogued as COSV57659092; called by muse, mutect2, varscan2
- ANKRD53 | c.764A>G p.N255S | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.779); catalogued as COSV55537001; called by muse, mutect2, varscan2
- ANKS1A | c.2305G>A p.G769R | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs370130506; called by muse, mutect2, varscan2
- ANO4 | c.2112G>T p.M704I (on ENST00000392977 / NM_001286615.2; = p.M669I on NM_178826.4) | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as rs1357371246, COSV54592706; called by muse, mutect2, varscan2
- API5 | c.1183C>T p.L395F | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV66632932; called by muse, mutect2, varscan2
- ARF5 | c.326A>T p.K109M | Missense Mutation (SNP) | VAF 22/114 reads (19%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.759); catalogued as COSV50000790; called by muse, mutect2, varscan2
- ATOH8 | c.692G>T p.R231L | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100092503; called by muse, mutect2
- BAZ2A | c.3242C>G p.S1081C | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV51634972; called by muse, mutect2, varscan2
- BMP1 | c.1765+1G>T p.X589_splice | Splice Site (SNP) | VAF 9/79 reads (11%) | catalogued as rs757046870, COSV60478249; called by muse, mutect2, varscan2
- C8orf34 | c.1358T>A p.M453K | Missense Mutation (SNP) | VAF 5/57 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.948); catalogued as COSV57401492; called by muse, mutect2, varscan2
- CAMTA1 | c.2123G>T p.G708V | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.554); catalogued as COSV57894894; called by muse, mutect2, varscan2
- CDH17 | c.1780G>T p.E594* | Nonsense Mutation (SNP) | VAF 9/103 reads (9%) | catalogued as COSV99217137; called by muse, mutect2
- CDK11A | c.145G>C p.E49Q | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.918); catalogued as rs1418476394, COSV62264696; called by muse, mutect2, varscan2
- CEMIP | c.3805C>G p.L1269V | Missense Mutation (SNP) | VAF 54/418 reads (13%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.991); catalogued as COSV54991137; called by muse, mutect2, varscan2
- CEP192 | c.6105A>G p.V2035= | Splice Region (SNP) | VAF 8/41 reads (20%) | catalogued as COSV58062712; called by muse, mutect2, varscan2
- CFAP251 | c.1733A>T p.N578I | Missense Mutation (SNP) | VAF 17/132 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.599); catalogued as COSV56609647; called by muse, mutect2, varscan2
- CHD2 | c.4810C>T p.Q1604* | Nonsense Mutation (SNP) | VAF 25/251 reads (10%) | catalogued as COSV101244917; called by muse, mutect2
- CKAP2 | c.1717C>G p.P573A (on ENST00000378037 / NM_001098525.2; = p.P572A on NM_018204.5) | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.021); catalogued as rs1439941086, COSV51621659; called by muse, mutect2, varscan2
- CLIP3 | c.599C>G p.S200* | Nonsense Mutation (SNP) | VAF 16/113 reads (14%) | catalogued as COSV100859300; called by muse, mutect2, varscan2
- CMKLR1 | c.16G>A p.E6K (on ENST00000312143 / NM_001142344.2; = p.E4K on NM_004072.3) | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV56437598; called by muse, mutect2, varscan2
- CNGB3 | c.786C>G p.I262M | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.102); catalogued as COSV100181101, COSV60688194; called by muse, mutect2, varscan2
- COL5A3 | c.4391C>T p.S1464L | Missense Mutation (SNP) | VAF 15/121 reads (12%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as COSV53408967, COSV53409257; called by muse, mutect2, varscan2
- CYP4A11 | c.1172G>C p.R391T | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV60223029, COSV60225344; called by muse, mutect2, varscan2
- CYTH4 | c.549C>T p.D183= | Splice Region (SNP) | VAF 19/131 reads (15%) | catalogued as COSV50631919; called by muse, mutect2, varscan2
- DDR2 | c.1466G>T p.R489L | Missense Mutation (SNP) | VAF 11/99 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.035); catalogued as COSV63370461, COSV63374100; called by muse, mutect2, varscan2
- DNAH7 | c.11110G>A p.A3704T | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT tolerated (0.53); PolyPhen benign (0.015); catalogued as COSV56760165; called by muse, mutect2, varscan2
- DNAJC12 | c.563A>T p.E188V | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.387); catalogued as COSV56547707; called by muse, mutect2, varscan2
- DOCK6 | c.4532C>T p.S1511L | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1232611062, COSV53913503; called by muse, mutect2, varscan2
- DOT1L | c.3608A>T p.K1203I | Missense Mutation (SNP) | VAF 25/107 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV67109140; called by muse, mutect2, varscan2
- EDIL3 | c.679A>C p.T227P | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56891777; called by muse, mutect2, varscan2
- EIF2AK2 | c.611C>G p.S204C | Missense Mutation (SNP) | VAF 17/103 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.285); catalogued as COSV51795896; called by muse, mutect2, varscan2
- EIF4A1 | c.233C>G p.S78C | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51510456, COSV51510463; called by muse, mutect2
- ELOVL7 | c.187G>A p.E63K | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.026); catalogued as COSV101415548; called by muse, mutect2, varscan2
- EPHA2 | c.2531C>T p.S844F | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); catalogued as rs1301152468, COSV64452795; called by muse, varscan2
- FAM120C | c.730G>A p.E244K | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.755); catalogued as COSV60258793; called by muse, mutect2, varscan2
- FBN3 | c.6771C>A p.H2257Q | Missense Mutation (SNP) | VAF 16/153 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0.023); catalogued as COSV54458396; called by muse, mutect2, varscan2
- FBXO5 | c.1024C>G p.Q342E | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.039); catalogued as COSV57670708; called by muse, mutect2, varscan2
- FLRT2 | c.1330C>G p.L444V | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs748353114, COSV58139805; called by muse, mutect2, varscan2
- GDF11 | c.1025C>T p.S342F | Missense Mutation (SNP) | VAF 29/188 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.416); catalogued as COSV57689526; called by muse, mutect2, varscan2
- GIMAP7 | c.653A>T p.E218V | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.111); catalogued as COSV57958950; called by muse, mutect2, varscan2
- GLG1 | c.637G>T p.E213* | Nonsense Mutation (SNP) | VAF 12/102 reads (12%) | catalogued as COSV99215504; called by muse, mutect2, varscan2
- GOLGA4 | c.4892C>G p.S1631* | Nonsense Mutation (SNP) | VAF 9/133 reads (7%) | catalogued as COSV100728751; called by muse, mutect2
- GORAB | c.631G>A p.D211N | Missense Mutation (SNP) | VAF 26/266 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV63026080; called by muse, mutect2
- GOT1L1 | c.893C>A p.T298N | Missense Mutation (SNP) | VAF 148/178 reads (83%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV56875243; called by muse, mutect2, varscan2
- GPC5 | c.1693G>T p.V565L | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.001); catalogued as COSV65591685; called by muse, mutect2, varscan2
- GPR6 | c.1012C>T p.R338C | Missense Mutation (SNP) | VAF 18/208 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV51571641; called by muse, mutect2
- GRHL1 | c.1148C>T p.S383F | Missense Mutation (SNP) | VAF 38/305 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61407576; called by muse, mutect2, varscan2
- GRIPAP1 | c.2277C>A p.I759= | Splice Region (SNP) | VAF 8/42 reads (19%) | catalogued as rs144855492, COSV54413534, COSV54415427; called by muse, mutect2, varscan2
- GUCY2C | c.967C>G p.L323V | Missense Mutation (SNP) | VAF 14/115 reads (12%) | SIFT tolerated (0.64); PolyPhen benign (0.015); catalogued as COSV53789110; called by muse, mutect2, varscan2
- HAS3 | c.277G>T p.A93S | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV54706609; called by muse, mutect2, varscan2
- HAS3 | c.278C>T p.A93V | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV54706634; called by muse, mutect2, varscan2
- HERC4 | c.2986C>T p.R996C (on ENST00000395198 / NM_022079.3; = p.R988C on NM_015601.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/122 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53017780; called by muse, mutect2
- HOXA13 | c.953C>G p.S318C | Missense Mutation (SNP) | VAF 39/106 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.358); catalogued as rs146259736, COSV56083441; called by muse, mutect2, varscan2
- HPS3 | c.526G>C p.E176Q | Missense Mutation (SNP) | VAF 12/101 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV56053813; called by muse, mutect2, varscan2
- HRG | c.94G>A p.E32K | Missense Mutation (SNP) | VAF 30/84 reads (36%) | SIFT tolerated (0.43); PolyPhen benign (0.015); catalogued as rs1374808119, COSV51644970; called by muse, mutect2, varscan2
- HRNR | c.6272C>G p.S2091C | Missense Mutation (SNP) | VAF 11/151 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as rs759882682, COSV100913161; called by muse, mutect2
- HTR5A | c.688C>A p.R230S | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.265); catalogued as COSV55282302, COSV55284114; called by muse, mutect2, varscan2
- HUWE1 | c.5044C>G p.L1682V | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT tolerated (0.3); PolyPhen benign (0.041); catalogued as COSV53342260; called by muse, mutect2, varscan2
- IPO8 | c.876C>G p.F292L | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.029); catalogued as COSV56240907; called by muse, mutect2, varscan2
- ITPRIPL1 | c.52G>A p.A18T (on ENST00000439118 / NM_001008949.3; = p.A26T on NM_178495.6) | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV63153060; called by muse, mutect2
- KIF4A | c.883C>G p.R295G | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65542653; called by muse, mutect2, varscan2
- KLHL12 | c.1162G>C p.D388H | Missense Mutation (SNP) | VAF 23/163 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66127237; called by muse, mutect2, varscan2
- KMT2A | c.7764T>A p.Y2588* | Nonsense Mutation (SNP) | VAF 34/63 reads (54%) | catalogued as COSV100628338; called by muse, mutect2, varscan2
- KMT2D | c.15629A>C p.Y5210S | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as CM111924, COSV56429345; called by muse, mutect2, varscan2
- KMT2E | c.4688C>G p.S1563C | Missense Mutation (SNP) | VAF 18/144 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); catalogued as COSV57572030; called by muse, mutect2, varscan2
- KRTAP23-1 | c.80G>T p.G27V | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT tolerated, low confidence (0.29); PolyPhen probably damaging (0.988); catalogued as COSV61935620; called by muse, mutect2, varscan2
- LAMA4 | c.1184T>A p.I395N (on ENST00000230538 / NM_001105206.3; = p.I388N on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV57895373; called by muse, mutect2, varscan2
- LILRB5 | c.1472C>T p.S491L (on ENST00000449561 / NM_001081442.3; = p.S490L on NM_006840.5) | Missense Mutation (SNP) | VAF 19/194 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as rs773967459, COSV60256571; called by muse, mutect2, varscan2
- LRRC31 | c.547G>A p.V183M | Missense Mutation (SNP) | VAF 19/126 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV52980424; called by muse, mutect2, varscan2
- LRRC4C | c.1828_1830del p.T610del | In Frame Del (DEL) | VAF 21/98 reads (21%) | catalogued as rs762387489; called by pindel, varscan2
- MAML3 | c.1789C>G p.L597V | Missense Mutation (SNP) | VAF 58/398 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); catalogued as COSV59073139; called by muse, mutect2, varscan2
- MAPT | c.1384G>A p.G462R (on ENST00000262410 / NM_001377265.1; = p.G136R on NM_005910.5) | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV52239267; called by muse, mutect2, varscan2
- MEIOC | c.1758T>G p.N586K | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV100740136, COSV63439787; called by muse, mutect2, varscan2
- MEIS2 | c.296C>T p.A99V (on ENST00000561208 / NM_170675.5; = p.A86V on NM_002399.3) | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54934052; called by muse, mutect2, varscan2
- MEP1B | c.1268C>T p.S423L | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs375895692; called by muse, mutect2, varscan2
- MLH1 | c.1889T>C p.I630T | Missense Mutation (SNP) | VAF 27/186 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV51616814, COSV51621278; called by muse, mutect2, varscan2
- MYCN | c.147C>G p.I49M | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99808136; called by muse, mutect2
- NAALAD2 | c.1171A>C p.S391R | Missense Mutation (SNP) | VAF 18/148 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV58960192; called by muse, mutect2, varscan2
- NBPF1 | c.757G>T p.D253Y | Missense Mutation (SNP) | VAF 20/188 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs774910170, COSV101236298; called by muse, mutect2
- NBPF3 | c.184G>A p.G62S | Missense Mutation (SNP) | VAF 18/222 reads (8%) | SIFT tolerated (0.26); PolyPhen benign (0.024); catalogued as rs201079583, COSV59058372; called by muse, mutect2
- NCBP2L | c.23T>A p.L8Q | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.034); catalogued as COSV64943886; called by muse, mutect2, varscan2
- NCKAP5L | c.3496C>G p.L1166V | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.44); PolyPhen benign (0.023); catalogued as COSV60128925; called by muse, mutect2, varscan2
- NCOA3 | c.2522G>C p.S841T | Missense Mutation (SNP) | VAF 12/132 reads (9%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.776); catalogued as COSV59067598; called by muse, mutect2
- NHLRC4 | c.116C>T p.S39F | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.753); catalogued as COSV50312904; called by muse, mutect2, varscan2
- NISCH | c.1102G>A p.E368K | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.092); catalogued as COSV61899428; called by muse, mutect2
- NOD2 | c.1342T>C p.S448P | Missense Mutation (SNP) | VAF 18/118 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56049709; called by muse, mutect2, varscan2
- NOM1 | c.2064A>C p.E688D | Missense Mutation (SNP) | VAF 63/190 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.762); catalogued as COSV51979662; called by muse, mutect2, varscan2
- NSUN6 | c.1093G>C p.E365Q | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.012); catalogued as rs757297367, COSV66032763; called by muse, mutect2
- NUP88 | c.1099G>C p.E367Q | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs374723055, COSV56704851; called by muse, mutect2, varscan2
- NXPE4 | c.1467C>A p.D489E (on ENST00000375478 / NM_001077639.2; = p.D205E on NM_017678.3) | Missense Mutation (SNP) | VAF 30/98 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV64943662; called by muse, mutect2, varscan2
- OPRD1 | c.730C>T p.R244C | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV52381615; called by muse, mutect2, varscan2
- OR2M5 | c.473T>C p.I158T | Missense Mutation (SNP) | VAF 95/319 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.137); catalogued as rs1327189135, COSV63546070; called by muse, varscan2
- OR56B4 | c.68T>A p.L23* | Nonsense Mutation (SNP) | VAF 22/63 reads (35%) | catalogued as COSV100337644; called by muse, mutect2, varscan2
- OR8B12 | c.169C>T p.P57S | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as COSV60911523; called by muse, mutect2, varscan2
- OR8H2 | c.239C>A p.P80H | Missense Mutation (SNP) | VAF 154/458 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57944135, COSV99046876; called by muse, varscan2
- PARPBP | c.1084G>A p.E362K | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.088); catalogued as rs779839262, COSV59672544; called by muse, mutect2, varscan2
- PCDHGA8 | c.928G>A p.E310K | Missense Mutation (SNP) | VAF 12/131 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.964); catalogued as COSV53929879; called by muse, mutect2
- PCGF1 | c.111G>C p.K37N | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.018); catalogued as COSV52042559; called by muse, mutect2, varscan2
- PCNX1 | c.43G>A p.A15T | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV53089600; called by muse, mutect2
- PDP1 | c.1231A>T p.K411* | Nonsense Mutation (SNP) | VAF 16/134 reads (12%) | catalogued as COSV99892136; called by muse, mutect2, varscan2
- PDSS1 | c.245C>A p.P82Q | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV66058758, COSV66059141; called by muse, mutect2, varscan2
- PLEKHH2 | c.3982C>T p.R1328W | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs374815272; called by muse, mutect2, varscan2
- POMGNT1 | c.1847G>A p.R616Q | Missense Mutation (SNP) | VAF 3/16 reads (19%) | PolyPhen benign (0.251); catalogued as rs775534917, COSV100915468; called by muse, mutect2
- POU6F2 | c.1096T>A p.L366M | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV68871979; called by muse, mutect2, varscan2
- PPP1R14A | c.202G>A p.E68K | Missense Mutation (SNP) | VAF 24/193 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV56646374; called by muse, mutect2, varscan2
- PPP1R1B | c.294G>C p.E98D | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT tolerated (0.4); PolyPhen benign (0.013); catalogued as COSV54201915; called by muse, mutect2, varscan2
- PRKCG | c.226C>T p.R76* | Nonsense Mutation (SNP) | VAF 27/92 reads (29%) | catalogued as COSV99668711; called by muse, mutect2, varscan2
- RAD51B | c.743A>C p.E248A | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.519); catalogued as COSV66846546; called by muse, mutect2, varscan2
- RAG1 | c.1130C>G p.S377* | Nonsense Mutation (SNP) | VAF 7/81 reads (9%) | catalogued as COSV55028559; called by muse, mutect2
- RBL1 | c.859G>A p.E287K | Missense Mutation (SNP) | VAF 20/128 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60329471; called by muse, mutect2, varscan2
- RFC5 | c.769C>G p.Q257E | Missense Mutation (SNP) | VAF 50/190 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV57477474; called by muse, mutect2, varscan2
- RFC5 | c.971C>G p.S324C | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as COSV57477480; called by muse, varscan2
- RHOBTB3 | c.1072G>A p.E358K | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.069); catalogued as COSV66101811; called by muse, mutect2, varscan2
- RIPPLY2 | c.346G>C p.D116H | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV63746409; called by muse, mutect2, varscan2
- RNF213 | c.2235A>C p.R745S | Missense Mutation (SNP) | VAF 14/132 reads (11%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as COSV60622184; called by muse, mutect2
- RPGR | c.2707-1G>C p.X903_splice (on ENST00000339363 / NM_001367249.1; = p.X698_splice on NM_000328.3 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 8/49 reads (16%) | catalogued as COSV58834256; called by muse, mutect2, varscan2
- RSRP1 | c.92C>G p.S31W | Missense Mutation (SNP) | VAF 13/104 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV54562477; called by mutect2, varscan2
- RYR1 | c.5309C>T p.S1770L | Missense Mutation (SNP) | VAF 10/97 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.32); catalogued as rs398123472, COSV62093143; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RYR2 | c.14358C>A p.F4786L | Missense Mutation (SNP) | VAF 63/254 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV63679194; called by muse, mutect2, varscan2
- SEMA3D | c.799T>G p.S267A | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as COSV52391549; called by muse, mutect2, varscan2
- SERAC1 | c.425C>G p.S142* | Nonsense Mutation (SNP) | VAF 19/158 reads (12%) | catalogued as COSV100894814; called by muse, mutect2, varscan2
- SHROOM4 | c.3736G>A p.G1246R | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV56787884; called by muse, mutect2, varscan2
- SIDT1 | c.1072C>G p.P358A | Missense Mutation (SNP) | VAF 5/59 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.338); catalogued as COSV53500222; called by muse, mutect2
- SLC20A1 | c.200G>A p.S67N | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV55610040; called by muse, mutect2, varscan2
- SLC24A1 | c.3194G>C p.R1065T | Missense Mutation (SNP) | VAF 9/145 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.782); catalogued as COSV56051247; called by muse, mutect2
- SLC44A2 | c.1598A>T p.E533V | Missense Mutation (SNP) | VAF 16/111 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.039); catalogued as rs1214830630, COSV59836281; called by muse, mutect2, varscan2
- SOAT1 | c.749C>T p.P250L | Missense Mutation (SNP) | VAF 25/249 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.893); catalogued as COSV62653743; called by muse, varscan2
- STK31 | c.1954A>T p.N652Y | Missense Mutation (SNP) | VAF 40/106 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.075); catalogued as COSV63455457; called by muse, mutect2, varscan2
- STYXL1 | c.532G>C p.D178H | Missense Mutation (SNP) | VAF 7/108 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV50388359; called by muse, mutect2
- SYNE2 | c.637G>C p.G213R | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58360459; called by muse, mutect2, varscan2
- SYNE3 | c.166G>A p.E56K | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs376779070, COSV62077729; called by muse, mutect2, varscan2
- TACR3 | c.486C>A p.N162K | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59200328; called by muse, mutect2, varscan2
- TAF9 | c.683C>T p.T228I | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.367); catalogued as COSV54204475; called by muse, mutect2, varscan2
- TCTN2 | c.703C>G p.L235V | Missense Mutation (SNP) | VAF 41/349 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.248); catalogued as COSV57632267; called by muse, mutect2, varscan2
- TMEM132D | c.551G>A p.R184Q | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.015); catalogued as rs756539559, COSV70601435, COSV70624212; called by muse, mutect2, varscan2
- TNXB | c.9166G>C p.E3056Q (on ENST00000647633; = p.E2809Q on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/94 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0.108); catalogued as COSV64477366, COSV64486489, COSV64487656; called by muse, mutect2, varscan2
- TRAPPC12 | c.1804T>G p.Y602D | Missense Mutation (SNP) | VAF 6/81 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.931); catalogued as COSV60846833; called by muse, mutect2
- TRHDE | c.1108C>G p.L370V | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs149888041; called by muse, mutect2
- TRIP10 | c.1408G>T p.E470* (on ENST00000313244 / NM_001288962.2; = p.E414* on NM_004240.4) | Nonsense Mutation (SNP) | VAF 18/108 reads (17%) | catalogued as COSV99837868; called by muse, mutect2, varscan2
- TSEN2 | c.106G>A p.E36K | Missense Mutation (SNP) | VAF 11/99 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.223); catalogued as rs1028831522, COSV53188420, COSV53188469, COSV53189713; called by muse, mutect2, varscan2
- TSHZ3 | c.3122A>T p.Y1041F | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (1); PolyPhen possibly damaging (0.5); catalogued as COSV53669075; called by muse, mutect2, varscan2
- TTC3 | c.2768C>T p.S923F | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.564); catalogued as COSV61289262; called by muse, mutect2
- TTN | c.88098C>G p.I29366M (on ENST00000591111; = p.I21942M on NM_003319.4) | Missense Mutation (SNP) | VAF 10/169 reads (6%) | PolyPhen possibly damaging (0.468); catalogued as COSV59993200; called by muse, mutect2
- UBE3A | c.2297A>G p.D766G | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51663836; called by muse, mutect2, varscan2
- UBN2 | c.4022A>C p.K1341T | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.833); catalogued as COSV56029653; called by muse, mutect2, varscan2
- UBQLN2 | c.335C>G p.S112C | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.775); catalogued as COSV57739364; called by muse, mutect2, varscan2
- ULK1 | c.1519C>G p.Q507E | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.37); PolyPhen benign (0.139); catalogued as COSV58855959; called by muse, mutect2, varscan2
- UNC79 | c.1457A>T p.D486V (on ENST00000393151 / NM_001346218.2; = p.D309V on NM_020818.5) | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.571); catalogued as COSV56383090; called by muse, mutect2, varscan2
- ZDBF2 | c.3251C>G p.S1084C | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as COSV65624412; called by muse, mutect2, varscan2
- ZDHHC20 | c.497C>G p.S166C | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV100203369; called by muse, mutect2
- ZNF106 | c.3517G>A p.G1173R | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.048); catalogued as COSV55513712; called by muse, mutect2, varscan2
- ZNF514 | c.1023G>C p.E341D | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV54633769; called by muse, mutect2, varscan2
- ZNF599 | c.920G>C p.R307P | Missense Mutation (SNP) | VAF 16/127 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.234); catalogued as COSV100251340, COSV61395925; called by muse, mutect2, varscan2
- ZNFX1 | c.3805G>A p.E1269K | Missense Mutation (SNP) | VAF 11/166 reads (7%) | SIFT tolerated (0.31); PolyPhen benign (0.005); catalogued as COSV65596267; called by muse, mutect2
- ACTB | c.943_945del p.K315del | In Frame Del (DEL) | VAF 37/149 reads (25%) | called by mutect2, pindel, varscan2
- CYFIP1 | c.695C>G p.S232C | Missense Mutation (SNP) | VAF 43/179 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.325); called by muse, mutect2, varscan2
- DDX59 | c.842G>C p.R281T | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MRC1 | c.3034A>G p.N1012D | Missense Mutation (SNP) | VAF 38/354 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- MRC1 | c.3718C>T p.P1240S | Missense Mutation (SNP) | VAF 56/505 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- TRBV28 | c.142C>T p.H48Y | Missense Mutation (SNP) | VAF 5/59 reads (8%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.861); called by muse, mutect2
- AAR2 | c.141C>T p.G47= | Silent (SNP) | VAF 8/58 reads (14%) | catalogued as rs762620736, COSV57923811; called by muse, mutect2, varscan2
- ADAM29 | c.2244C>A p.S748= | Silent (SNP) | VAF 18/128 reads (14%) | catalogued as COSV63662618, COSV63668077; called by muse, mutect2, varscan2
- ARHGEF25 | c.186C>T p.L62= | Silent (SNP) | VAF 26/74 reads (35%) | catalogued as COSV54085906; called by muse, varscan2
- ATP8B4 | c.3288G>C p.L1096= | Silent (SNP) | VAF 11/75 reads (15%) | catalogued as COSV52713527; called by muse, mutect2, varscan2
- CACNA2D2 | c.522G>A p.E174= | Silent (SNP) | VAF 38/199 reads (19%) | catalogued as COSV56562572; called by muse, mutect2, varscan2
- CALCOCO2 | c.1110A>G p.Q370= | Silent (SNP) | VAF 10/106 reads (9%) | catalogued as COSV51951683; called by muse, mutect2, varscan2
- CDCA2 | c.1167G>A p.K389= | Silent (SNP) | VAF 12/40 reads (30%) | catalogued as COSV57945491; called by muse, mutect2, varscan2
- CLIP3 | c.297C>T p.I99= | Silent (SNP) | VAF 5/79 reads (6%) | catalogued as rs907294430, COSV100859360, COSV62112256; called by muse, mutect2
- CRTC3 | c.219G>A p.A73= | Silent (SNP) | VAF 6/54 reads (11%) | catalogued as rs192214530, COSV51595867; called by mutect2, varscan2
- DIRAS1 | c.81C>T p.F27= | Silent (SNP) | VAF 13/68 reads (19%) | catalogued as rs762064600, COSV60215445; called by muse, mutect2, varscan2
- DPYD | c.897G>A p.Q299= | Silent (SNP) | VAF 13/107 reads (12%) | catalogued as rs1383131499, COSV64595133; called by muse, mutect2, varscan2
- EDIL3 | c.678T>A p.V226= | Silent (SNP) | VAF 11/74 reads (15%) | catalogued as COSV56891784; called by muse, mutect2, varscan2
- EMILIN2 | c.2847T>C p.D949= | Silent (SNP) | VAF 8/61 reads (13%) | catalogued as COSV54422769; called by muse, mutect2, varscan2
- EPHA2 | c.2490C>A p.I830= | Silent (SNP) | VAF 8/38 reads (21%) | catalogued as COSV64452801; called by muse, varscan2
- EPHX3 | c.570C>A p.V190= | Silent (SNP) | VAF 14/60 reads (23%) | catalogued as COSV55655345; called by muse, mutect2, varscan2
- EPHX4 | c.540C>T p.I180= | Silent (SNP) | VAF 6/80 reads (8%) | catalogued as COSV64889379; called by muse, mutect2
- FAT4 | c.8949T>C p.P2983= | Silent (SNP) | VAF 8/59 reads (14%) | catalogued as rs766890007, COSV58680055; called by muse, mutect2, varscan2
- FBXL20 | c.222G>A p.Q74= | Silent (SNP) | VAF 4/54 reads (7%) | catalogued as COSV99233891; called by muse, mutect2
- FSCN3 | c.997C>T p.L333= | Silent (SNP) | VAF 58/148 reads (39%) | catalogued as rs1562956506, COSV56168941; called by muse, mutect2, varscan2
- GABPA | c.1122C>T p.L374= | Silent (SNP) | VAF 5/73 reads (7%) | catalogued as COSV61395996; called by muse, mutect2
- GCSAML | c.225C>T p.I75= | Silent (SNP) | VAF 13/89 reads (15%) | catalogued as COSV63577526; called by muse, mutect2, varscan2
- GFOD2 | c.603C>G p.L201= | Silent (SNP) | VAF 7/54 reads (13%) | catalogued as rs1555544708, COSV52057666; called by muse, mutect2, varscan2
- GPC5 | c.1692G>T p.V564= | Silent (SNP) | VAF 14/95 reads (15%) | catalogued as COSV65591682; called by muse, mutect2, varscan2
- GPR149 | c.864C>T p.C288= | Silent (SNP) | VAF 44/137 reads (32%) | catalogued as COSV67666875; called by muse, mutect2, varscan2
- GRB2 | c.273T>A p.A91= | Silent (SNP) | VAF 17/126 reads (13%) | catalogued as COSV100353629, COSV57304179; called by muse, mutect2, varscan2
- HCAR2 | c.1032G>A p.A344= | Silent (SNP) | VAF 26/217 reads (12%) | catalogued as rs201282262, COSV61024750, COSV61025699; called by muse, mutect2, varscan2
- HECTD1 | c.96C>T p.C32= | Silent (SNP) | VAF 12/80 reads (15%) | catalogued as COSV67945885; called by muse, mutect2, varscan2
- HNRNPUL1 | c.507G>A p.Q169= | Silent (SNP) | VAF 47/264 reads (18%) | catalogued as COSV54561685; called by muse, mutect2, varscan2
- HRG | c.1098C>T p.P366= | Silent (SNP) | VAF 3/14 reads (21%) | catalogued as COSV51644835, COSV99214668; called by muse, mutect2
- KRTAP4-1 | c.168G>A p.Q56= | Silent (SNP) | VAF 7/53 reads (13%) | catalogued as COSV66648184; called by muse, mutect2, varscan2
- LCP1 | c.1182G>A p.T394= | Silent (SNP) | VAF 9/58 reads (16%) | catalogued as rs1340124965, COSV59940524; called by muse, mutect2, varscan2
- LEFTY2 | c.273G>A p.A91= | Silent (SNP) | VAF 6/41 reads (15%) | catalogued as rs372862888; called by muse, mutect2, varscan2
- MAML2 | c.3132C>T p.L1044= | Silent (SNP) | VAF 12/41 reads (29%) | catalogued as COSV73263195, COSV73264077; called by muse, mutect2, varscan2
- MDGA2 | c.1254C>A p.I418= (on ENST00000399232 / NM_001113498.2; = p.I120= on NM_182830.4) | Silent (SNP) | VAF 11/59 reads (19%) | catalogued as COSV62087165; called by muse, mutect2, varscan2
- MGAT5 | c.1155A>G p.E385= | Silent (SNP) | VAF 8/101 reads (8%) | catalogued as rs1245774512, COSV56095705; called by muse, mutect2
- MTMR8 | c.615T>C p.C205= | Silent (SNP) | VAF 6/76 reads (8%) | catalogued as COSV66393304; called by muse, mutect2
- NOX4 | c.27C>T p.L9= | Silent (SNP) | VAF 13/83 reads (16%) | catalogued as rs769797957, COSV54451320; called by muse, mutect2, varscan2
- NPHP4 | c.486C>G p.L162= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as COSV65394424; called by muse, mutect2
- OR2M3 | c.552A>G p.L184= | Silent (SNP) | VAF 64/246 reads (26%) | catalogued as COSV101513389, COSV71758990; called by muse, mutect2, varscan2
- OR7A5 | c.246G>A p.L82= | Silent (SNP) | VAF 24/185 reads (13%) | catalogued as rs772203973, COSV59234495; called by muse, mutect2, varscan2
- OXR1 | c.2349G>A p.L783= (on ENST00000442977 / NM_001198532.1; = p.L755= on NM_018002.3) | Silent (SNP) | VAF 11/72 reads (15%) | catalogued as COSV52424968; called by muse, mutect2, varscan2
- PCDHA1 | c.1185C>T p.F395= | Silent (SNP) | VAF 30/156 reads (19%) | catalogued as COSV65373754, COSV65374180; called by muse, mutect2, varscan2
- PCDHGA5 | c.1719G>A p.T573= | Silent (SNP) | VAF 35/201 reads (17%) | catalogued as rs542025009, COSV53916577; called by muse, mutect2, varscan2
- PIWIL1 | c.289C>T p.L97= | Silent (SNP) | VAF 10/68 reads (15%) | catalogued as rs762300056, COSV55345867; called by muse, mutect2, varscan2
- PKD1L1 | c.5739C>A p.T1913= | Silent (SNP) | VAF 6/48 reads (13%) | catalogued as COSV56962883; called by muse, mutect2, varscan2
- PRAMEF17 | c.1059C>T p.I353= | Silent (SNP) | VAF 22/202 reads (11%) | called by muse, mutect2, varscan2
- PXDNL | c.3567C>T p.G1189= | Silent (SNP) | VAF 15/44 reads (34%) | catalogued as COSV62485379; called by muse, mutect2, varscan2
- ROR2 | c.723G>T p.A241= | Silent (SNP) | VAF 14/30 reads (47%) | catalogued as COSV65218305; called by muse, mutect2, varscan2
- RYR2 | c.6298C>A p.R2100= | Silent (SNP) | VAF 10/43 reads (23%) | catalogued as rs753164125, COSV63679185, COSV63688704; called by muse, mutect2, varscan2
- SKAP2 | c.717T>C p.D239= | Silent (SNP) | VAF 18/49 reads (37%) | catalogued as COSV61722799; called by muse, mutect2, varscan2
- SLC28A1 | c.66G>A p.E22= | Silent (SNP) | VAF 8/78 reads (10%) | catalogued as COSV54478231; called by muse, mutect2
- SLC37A1 | c.1002G>A p.L334= | Silent (SNP) | VAF 15/136 reads (11%) | catalogued as COSV61402091, COSV61402165; called by muse, mutect2, varscan2
- SLC7A13 | c.1302A>G p.L434= | Silent (SNP) | VAF 17/51 reads (33%) | catalogued as COSV52533528; called by muse, mutect2, varscan2
- SLX4IP | c.498G>C p.L166= | Silent (SNP) | VAF 11/49 reads (22%) | catalogued as COSV100570305, COSV57947547; called by muse, mutect2
- SP2 | c.1272G>A p.L424= | Silent (SNP) | VAF 9/55 reads (16%) | catalogued as rs773392267, COSV65063855; called by muse, mutect2, varscan2
- TAF1 | c.4167C>G p.V1389= (on ENST00000373790 / NM_138923.4; = p.V1410= on NM_004606.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 19/72 reads (26%) | catalogued as COSV52111268; called by muse, mutect2, varscan2
- TMEM39A | c.1147C>T p.L383= | Silent (SNP) | VAF 26/85 reads (31%) | catalogued as COSV59900141; called by muse, mutect2, varscan2
- TPRG1 | c.108G>C p.P36= | Silent (SNP) | VAF 6/121 reads (5%) | catalogued as COSV61464529, COSV61469234; called by muse, mutect2
- TSC2 | c.3270C>T p.S1090= | Silent (SNP) | VAF 9/93 reads (10%) | catalogued as rs754951889, COSV54761877; ClinVar: benign / uncertain significance / likely benign; called by muse, mutect2, varscan2
- UHRF1BP1L | c.99A>G p.E33= | Silent (SNP) | VAF 10/68 reads (15%) | catalogued as COSV54436298; called by muse, mutect2, varscan2
- VPS11 | c.618C>G p.L206= (on ENST00000620429; = p.L750= on NM_021729.6 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 18/75 reads (24%) | catalogued as COSV100333633, COSV100333846, COSV100334056; called by muse, mutect2, varscan2
- WAS | c.93G>A p.E31= | Silent (SNP) | VAF 17/100 reads (17%) | catalogued as CM961451, COSV64996919; called by muse, mutect2, varscan2
- YEATS2 | c.609A>T p.R203= | Silent (SNP) | VAF 7/58 reads (12%) | catalogued as COSV59364337; called by muse, mutect2, varscan2
- ZNF236 | c.4056G>A p.G1352= | Silent (SNP) | VAF 8/67 reads (12%) | catalogued as COSV53486178, COSV53489333; called by muse, mutect2, varscan2
- AL132655.6 | chr20:58840836 C>A | 5'Flank (SNP) | VAF 4/43 reads (9%) | catalogued as COSV100005834, COSV100007453, COSV100007872; called by muse, mutect2
- GRIA4 | c.2544+56T>C | Intron (SNP) | VAF 33/75 reads (44%) | catalogued as COSV56891205; called by muse, mutect2, varscan2
- LINC00173 | n.955C>T | RNA (SNP) | VAF 11/61 reads (18%) | called by muse, mutect2, varscan2
- LINC02843 | n.463dup | RNA (INS) | VAF 4/40 reads (10%) | called by mutect2, pindel
- MACROD2 | c.1315+3307C>G | Intron (SNP) | VAF 5/42 reads (12%) | catalogued as COSV53971840; called by muse, mutect2, varscan2
- MIR520H | n.61T>C | RNA (SNP) | VAF 23/106 reads (22%) | catalogued as rs1274322077; called by muse, mutect2, varscan2
- NIN | c.-21-1157C>T | Intron (SNP) | VAF 8/59 reads (14%) | catalogued as COSV99812503; called by muse, mutect2, varscan2
